Somatic mutation profile of tumor specimen 0DYB13 from CCDI case PBCSCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,096 days).
Specimen 0DYB13: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01cb773b-21f1-4c4d-bcc4-b554adc966b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYB0M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f519672-5f34-4849-8d16-469c0e7844df

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'UTR 2, Nonsense Mutation 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 102/212 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HDAC4 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61870119; called by muse, mutect2, varscan2
- HYOU1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs782669905; called by muse, mutect2, varscan2
- NKAIN4 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.944); catalogued as rs775670008, COSV64787613; called by muse, mutect2, varscan2
- OR5D13 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 58/660 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1305440250; called by muse, mutect2
- TARS2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 140/403 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201748553; called by muse, mutect2, varscan2
- WAC | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 131/462 reads (28%) | catalogued as CM1211475, COSV61566711; called by muse, mutect2, varscan2
- DSPP | c.2227A>G p.S743G | Missense Mutation (SNP) | VAF 55/1137 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.437); called by muse, mutect2
- KBTBD4 | c.889_890insTCCGGC p.R296_R297insLR | In Frame Ins (INS) | VAF 88/353 reads (25%) | called by mutect2, pindel, varscan2
- PCNX1 | c.1348A>G p.S450G | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- TRIM10 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADORA3 | c.510C>T p.S170= | Silent (SNP) | VAF 129/482 reads (27%) | catalogued as rs373163241; called by muse, mutect2, varscan2
- FLRT3 | c.165A>G p.G55= | Silent (SNP) | VAF 34/651 reads (5%) | called by muse, mutect2
- PLVAP | c.681C>T p.P227= | Silent (SNP) | VAF 48/527 reads (9%) | catalogued as COSV53086247; called by muse, mutect2
- DCC | c.*3940A>G | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- PAFAH1B1 | c.1160-24A>G | Intron (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SAFB2 | c.*34C>T | 3'UTR (SNP) | VAF 44/490 reads (9%) | catalogued as rs374028961; called by muse, mutect2
